Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8DG, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8DG-01A (Primary Tumor).

[page 1 of 4]
Operative Procedure:

Right VATS, possible mini thoracotomy, lobectomy

Pre-Operative Diagnosis:

As below

Post-Operative Diagnosis:

As below

Specimen Received:

- A: right middle lobe nodule (FS)
- B: posterior right lower lobe (FS)
- C: portion of thymus pericardial fat pool
- D: thymic tumor (stitch = superior aspect)(FS)
- E: additional thymus - medial

Final Pathologic Diagnosis:

- A. Lung, right middle lobe, nodule, resection:
- Necrotizing granulomatous inflammation.
- AFB and GMS stainings were negative for organisms.
- Negative for malignancy.
- Frozen section diagnosis confirmed.
- B. Lung, posterior right lower lobe, resection:
- Acute and chronic bronchiolitis, bronchopneumonia and respiratory pneumonitis.
- Granulomatous inflammation.
- One lymph node, negative for malignancy (0/1).
- Frozen section diagnosis confirmed.
- C. Soft tissue, portion of thymus pericardial fat, resection:
- Unremarkable adipose tissue, negative for malignancy.
- D. Tumor, thymus, resection:
- Thymoma, mixed type B2/B1, predominantly B2 type.

Specimen: Thymus, lung, pericardial fat
Procedure: Thymectomy, lobectomy
Specimen integrity: Intact
Specimen weight: 136 g
Tumor size: 7 x 6.5 x 3.5 cm (greatest dimension)
Histologic type: Thymoma
Tumor extension: Encapsulated confined in thymus
Margins: Margins uninvolved by tumor
Distance of tumor from closest margin: 1 mm
Specify margin: Resection margin
Treatment effect: No treatment effect identified

case ID-0.3
Thymoma, type B2 NOS 8584/1
with Thymoma, mixed type NOS 8582/1
Site: Thymus C37.9
4/6/13/14

[page 2 of 4]
Lymph-vascular invasion: Not identified

Regional lymph nodes:

Number examined: 12

Number involved: 0

Pathologic Staging for Thymomas (Modified Masaoka Stage): Stage: Grossly and microscopically encapsulated

Implants/distant metastasis: Cannot be assessed

Additional pathologic findings: None

Frozen section diagnosis confirmed.

E. Thymus, additional medial, resection:

Unremarkable adipose tissue, no thymus tissue identified.

Negative for malignancy.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA: Right middle lobe nodule:

Necrotizing granulomatous inflammation negative for carcinoma.

FSB: Posterior right lower lobe:

Lymph node negative for carcinoma.

FSA, FSB TAT: Time in , Time out elapsed time 23 mins/2 frozen sections)

FSD: Thymic tumor:

Lymphocyte rich neoplasm, favor thymoma.

TAT: Time in Time in (elapsed time 32 mins)

Gross Description:

The specimens are received in five containers, labeled with the patient name

Part A is received fresh for frozen section labeled "right middle lobe nodule" and consists of a previously inked, previously incised wedge of lung with overall reapproximated dimensions of 3.5 x 2.3 x 1.5 cm. The surgical edge is inked black. The cut surface is remarkable for tan-white nodularity with dimensions ranging from 0.2 to 0.7 cm. A portion of this nodular area is submitted for frozen section evaluation. These nodules approach the inked surgical edge within 0.1 cm. Representative sections are submitted as follows:

A1 residual frozen section tissue;

A2-4 additional sections of remaining specimen to include nodularity and inked surgical edge.

[page 3 of 4]
Part B is received fresh for frozen section labeled "right lower lobe" and consists of a previously incised wedge of lung with dimensions of 5 x 1 x 0.7 cm. The pleural surface is purple-tan, smooth to roughened. There is a staple line present without designation. The staple line is removed and the underlying tissue is inked. The cut surface is remarkable for a red-tan to white nodule that is 0.6 cm in greatest dimension. This nodule approaches the inked surgical edge within 0.2 cm. A representative portion is submitted for frozen section evaluation.

Representative sections are submitted as follows:

- B1 residual frozen section tissue;
- B2 additional section of remaining specimen.

Part C is received in formalin labeled "portion of thymus pericardial fat pad" and consists of a portion of yellow-tan fibroadipose tissue with overall dimensions of 8.5 x 6.5 by up to 2.7 cm. The specimen is received with no orientation. The weight of the specimen is 59 g. The external surface is inked. Sectioning reveals a yellow-tan, lobulated cut surface. No suspicious lesions are grossly appreciated. Representative sections are submitted in cassette C1-C4.

Part D is received fresh for frozen section labeled "thymic tumor, stitch equals superior aspect" and consists of a 136 g, 12 x 8 by up to 3.5 cm portion of yellow-tan predominately fibrofatty tissue. There is a single suture present designated superior aspect. The specimen is received partially inked and partially incised. The remaining specimen is inked blue. Additional sectioning reveals a tan-white, well-delineated mass that has dimensions of 7 x 6.5 by up to 3.5 cm. The mass is focally hemorrhagic and appears to be well encapsulated. The mass abuts the inked external surface. The remaining cut surfaces are yellow-tan, lobulated. Additional sectioning through the fibroadipose tissue reveals a few lymph nodes up to 0.8 cm.

Representative sections are submitted as follows:

- D1 residual frozen section tissue;
- D2 section near sutured superior aspect;
- D3-7 sections of mass submitted sequentially from superior to inferior (please note, all margins have been represented);
- D8,9 each with multiple whole lymph nodes.

Part E is received in formalin labeled "additional thymus medial" and consists of a 26 g, 7.5 x 4.8 x 2 cm aggregate of yellow-tan fibroadipose tissue fragments. Orientation is not provided or possible. Sectioning reveals yellow-tan, lobulated cut surfaces. No suspicious lesions are identified. Additional sectioning reveals a few possible lymph nodes up to 0.3 cm.

Representative sections are submitted as follows:

- E1-3 portions of fibroadipose tissue;
- E4 possible lymph nodes.

[page 4 of 4]
Microscopic Description:
The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Surgical Pathology Report

Taken: DOB: Gender: M

Criteria	10/31/13	Yes	No
Diagnostic Discrepancy			✓
Dual/Synchronous Primary	Noted		

Source: NCI Genomic Data Commons file f7ca29b5-bb1f-4284-a9b0-7dc058f85035 (TCGA-X7-A8DG.2519AB6C-93B4-4258-8201-FF815888015D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).